Gene-level copy-number profile of tumor specimen TCGA-25-2393-01A from TCGA case TCGA-25-2393, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 81.0 years (29,585 days).
Specimen TCGA-25-2393-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.dcc7bdda-71fa-4e79-8a0e-28259dc2cdaf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-25-2393-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a82f3346-109d-4f4f-89e9-0485ab7529c6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 2,183; copy number 2: 21,487; copy number 3: 27,434; copy number 4: 4,671; copy number 5: 2,488; copy number 6: 334; copy number 7: 295; copy number 8: 4; copy number 9: 2; copy number 10: 246; copy number 11: 202; copy number 12: 39; copy number 13: 119; copy number 14: 4; copy number 15: 58; copy number 16: 26; copy number 17: 8; copy number 18: 32; copy number 19: 31; copy number 22: 46; copy number 23: 64; copy number 25: 28; copy number 28: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-25-2393-01A-01D-0704-01): tumor purity 0.84, ploidy 2.88, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:159,231,435–159,233,377, 1 gene: PIP5K1P2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,210 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:37,717,579–43,674,591, 159 genes, copy number 11 (broad region; genes not listed).
- chr10:12,349,547–12,835,545, 1 gene, copy number 28 (within-gene range 2–28): CAMK1D.
- chr10:12,456,483–14,774,897, 44 genes, copy number 10–28 (within-gene range 2–28): RNU6ATAC39P, AL731559.1, MIR4480, MIR4481, MIR548Q, AL353586.1, CCDC3, RNA5SP300, RPL5P25, OPTN, SNRPGP5, AL355355.2, AL355355.1, BTBD7P1, RPL36AP36, MCM10, RNU6-6P, UCMA, PHYH, RBISP1, SEPHS1, AL355870.2, AL355870.1, BEND7, Y_RNA, AL590677.1, PRPF18, RPL6P24, AL157392.5, AL157392.3, FRMD4A, AL157392.4, AL157392.1, RNA5SP301, AL157392.2, NUTF2P5, AC044781.1, AL157896.1, AL139405.1, MIR4293, Metazoa_SRP, MIR1265, FAM107B, AL158168.1.
- chr10:17,214,239–18,043,292, 18 genes, copy number 11–16: VIM-AS1, VIM, AL133415.1, ST8SIA6, ST8SIA6-AS1, Y_RNA, PRPF38AP2, HACD1, AC069542.2, STAM-AS1, STAM, AC069542.1, TMEM236, MRC1, MIR511, AC069023.1, SLC39A12, SLC39A12-AS1.
- chr10:18,206,127–18,261,504, 1 gene, copy number 16 (within-gene range 2–16): AL390783.1.
- chr12:7,129,698–11,895,377, 221 genes, copy number 10–12 (within-gene range 4–12) (broad region; genes not listed).
- chr12:16,661,766–25,959,765, 127 genes, copy number 10–18 (broad region; genes not listed).
- chr12:31,111,652–31,252,597, 3 genes, copy number 8 (within-gene range 4–8): AC024940.1, AC024940.4, AC024940.2.
- chr12:66,950,754–72,186,618, 107 genes, copy number 15–25 (within-gene range 2–25) (broad region; genes not listed).
- chr16:1,333,638–7,713,340, 296 genes, copy number 7–8 (within-gene range 1–8) (broad region; genes not listed).
- chr18:21,704,957–21,870,953, 1 gene, copy number 13 (within-gene range 5–13): MIB1.
- chr18:21,793,883–28,177,946, 119 genes, copy number 13–25 (broad region; genes not listed).
- chr18:30,713,275–32,938,316, 57 genes, copy number 9–22 (within-gene range 5–22): AC090506.1, AC090506.2, AC016382.1, RNU6-857P, DSC3, DSC2, DSCAS, DSC1, AC012417.1, DSG1, DSG1-AS1, RNU6-167P, DSG4, Y_RNA, DSG3, AC021549.1, DSG2, DSG2-AS1, TTR, B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52, TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2, GAREM1, RNA5SP453, MEP1B, CLUHP6, AC015563.1, Y_RNA, AC015563.2, HNRNPA1P7, AC025887.2, WBP11P1, AC009835.1, AC025887.1, KLHL14, AC012123.1, AC012123.2, AC090371.2.
- chr22:15,290,718–16,748,645, 56 genes, copy number 10: AP000542.1, AP000542.2, ZNF72P, BNIP3P2, YME1L1P1, OR11H1, AP000534.2, ARHGAP42P3, AP000534.1, AP000533.2, AP000533.1, AP000533.3, AP000532.2, NEK2P2, AP000532.1, NF1P6, MED15P7, POTEH, POTEH-AS1, RNU6-816P, AP000529.1, PSLNR, GRAMD4P2, DUXAP8, AP000526.1, BMS1P22, AP000525.1, DUXAP8, NBEAP3, TOMM40P2, AP000522.1, AC145543.1, U6, ABCD1P4, AC137499.1, PABPC1P9, SLC9B1P4, ACTR3BP6, CHEK2P4, AP000547.2, AP000547.1, KCNMB3P1, CCT8L2, AP000547.4, FABP5P11, TPTEP1, AP000547.3, AP000365.1, SLC25A15P5, PARP4P3, ANKRD62P1-PARP4P3, ANKRD62P1, AC005301.1, VWFP1, AC005301.2, LINC01665.

Autosomal genes at a single copy (total copy number 1): 2,183. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
